Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8326, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8326-01A (Primary Tumor).

[page 1 of 2]
Other Related Data:

Billing Type:

Financial Number:

Clinical Diagnosis & History:

7cm right renal mass.

Specimens Submitted:

1: SP: Right kidney and adrenal

2: SP: Paracaval lymph node

DIAGNOSIS:

- 1) KIDNEY/ADRENAL, RIGHT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CHROMOPHOBE TYPE, EOSINOPHILIC VARIANT TUMOR MEASURES 6.3 CM IN GREATEST DIAMETER, AND INVOLVES THE UPPER POLE OF THE RIGHT KIDNEY.
- TUMOR INVADES THROUGH RENAL CAPSULE AND IS PRESENT WITHIN PERINEAL SOFT TISSUE (pT3a).
- NO VASCULAR INVASION IS IDENTIFIED.
- BENIGN URETER AND VASCULAR MARGINS.
- SURGICAL MARGINS ARE FREE OF TUMOR.
- BENIGN ADRENAL.
- BENIGN RENAL PARENCHYMA IS UNREMARKABLE.
- 2) PARACAVAL LYMPH NODE; EXCISION:
- FOURTEEN BENIGN LYMPH NODES (0/14).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL) AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

- 1) The specimen is received fresh, labeled "Right kidney and adrenal". It consists of a 880 grams of nephrectomy specimen. The specimen measures 23 x 10 x 8.5 cm. The specimen consists of kidney with surrounding perirenal soft tissue and attached proximal segment of the ureter. The right adrenal gland is also grossly identified at the upper pole of the specimen, measuring 4.2 x 2 x 0.9 cm. Grossly, a bulging renal mass is present at

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

the upper pole of the kidney. The specimen is bivalve along the ureter to reveal a relatively circumscribed tumor mass at the upper pole of the kidney measuring 6.3 cm in greatest diameter. The remaining kidney tissue measures 10 x 6.2 x 4 cm. The mass shows mosaic colors of brown, tan and grey area. The texture of the tumor is rubbery. No definite necrosis is identified. Focal scar is also present. The tumor appears to bulge and invades into the renal capsule. The tumor does not involve the renal cavity. No vascular involvement of the tumor is identified. The attached ureter measures approximately 7 cm in length and 0.4 to 0.5 cm in diameter. The proximal ureter shows dilated appearance and contains urine. The rest of the renal parenchyma is unremarkable. The cut section of the adrenal is unremarkable. Representative sections are submitted. A portion of tumor is sent for [REDACTED] and a small portion is kept in glutaraldehyde. No definite lymph nodes are identified within the hilar perirenal fat.

Summary of Sections:

T - tumor
R - random section of kidney
UM - ureteral margin
VM - vascular margin
ADR - adrenal

2) The specimen is received in formalin, labeled "Paracaval lymph node". It consists of two irregular pieces of yellow-tan fibroadipose tissue, measuring 4.5 x 3.0 x 1.5 cm in aggregate, possibly containing lymph nodes. The specimen is submitted entirely.

Summary of Sections:

U - Undesignated

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	ADR		1	1	N
	R		1	1	
	T		9	9	
	UM		1	1	
	VM		1	1	
2	U		6	M	Y

Source: NCI Genomic Data Commons file 9b09157a-6059-4b4f-96cb-73d964de34ef (TCGA-KL-8326.24E2925B-4F7B-40C0-87D4-68568F3FDF17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).